Somatic mutation profile of tumor specimen TCGA-59-2348-01A (aliquot TCGA-59-2348-01A-01D-0704-01) from TCGA case TCGA-59-2348, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-59-2348-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4ea703c-807c-4e79-aedd-f81f14b22333.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-2348-11A (Solid Tissue Normal), aliquot TCGA-59-2348-11A-01W-0800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6fd842e-1867-403e-93fa-9b8075824bb4

The open-access MAF lists 102 somatic variants for this specimen: 77 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 22, Frame Shift Del 6, Splice Site 4, Nonsense Mutation 2, Intron 2, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4502G>A p.R1501Q | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as rs200226002, COSV52204060; called by muse, mutect2, varscan2
- ADAR | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 47/370 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52717131; called by muse, mutect2, varscan2
- ADCY1 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1562735052, COSV52036386; called by muse, mutect2, varscan2
- AHNAK | c.13525A>C p.M4509L | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV57217434; called by muse, mutect2, varscan2
- AMY2B | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100796249, COSV63715171; called by muse, mutect2, varscan2
- APBB2 | c.1642-1G>A p.X548_splice (on ENST00000295974 / NM_001166050.2; = p.X549_splice on NM_004307.2) | Splice Site (SNP) | VAF 21/102 reads (21%) | catalogued as COSV55954929; called by muse, mutect2, varscan2
- ASIC5 | c.312G>T p.M104I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV72232920; called by muse, mutect2, varscan2
- ASPM | c.297+1G>T p.X99_splice | Splice Site (SNP) | VAF 30/284 reads (11%) | catalogued as CS107952, COSV54132156; called by muse, mutect2, varscan2
- BOLL | c.277-2A>C p.X93_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | catalogued as COSV56574957; called by muse, mutect2, varscan2
- CALCOCO1 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.63); catalogued as rs535194693, COSV50412611; called by muse, mutect2, varscan2
- CAPN6 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180439832, COSV60695485; called by muse, mutect2, varscan2
- CARD11 | c.2152T>G p.C718G | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV62755742; called by muse, mutect2, varscan2
- CLPTM1L | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV57991091; called by muse, mutect2
- COL5A3 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573860973, COSV53412888; called by muse, mutect2, varscan2
- CPNE9 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs745817621, COSV56068053, COSV99808553; called by muse, mutect2, varscan2
- CSMD2 | c.3632G>T p.C1211F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV53923573; called by muse, mutect2, varscan2
- CWH43 | c.1797T>G p.N599K | Missense Mutation (SNP) | VAF 17/299 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99893134; called by muse, mutect2
- CYP2A13 | c.385C>G p.R129G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57836399, COSV57838471; called by muse, mutect2, varscan2
- DZIP1 | c.1784G>A p.R595Q (on ENST00000347108; = p.R576Q on NM_014934.5) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1448735939, COSV61263815; called by muse, mutect2, varscan2
- EDRF1 | c.1859A>G p.K620R (on ENST00000356792 / NM_001202438.2; = p.K586R on NM_015608.2) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV100523376; called by muse, mutect2
- ELAPOR1 | c.315C>A p.D105E | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1414010554, COSV64045547; called by muse, varscan2
- EML5 | c.378_379insTGAA p.D127* | Nonsense Mutation (INS) | VAF 16/117 reads (14%) | catalogued as COSV100715363; called by mutect2, pindel, varscan2
- FBN3 | c.7743C>A p.S2581R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV54463895; called by muse, mutect2, varscan2
- FBXO27 | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.097); catalogued as COSV53072556; called by muse, mutect2, varscan2
- GABRE | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs374540437, COSV64820034; called by muse, mutect2, varscan2
- GCN1 | c.4580G>T p.C1527F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56109565; called by muse, mutect2, varscan2
- GIPC2 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867740917, COSV66128556, COSV66129091; called by muse, mutect2, varscan2
- GPR152 | c.890T>A p.M297K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV56886939; called by muse, mutect2
- GRID1 | c.780+1G>A p.X260_splice | Splice Site (SNP) | VAF 23/91 reads (25%) | catalogued as COSV60035007; called by muse, mutect2, varscan2
- GTF2B | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 35/203 reads (17%) | catalogued as rs772494214, COSV65137090; called by muse, mutect2, varscan2
- HEXD | c.1130G>A p.R377H (on ENST00000327949 / NM_001369487.1; = p.A407T on NM_173620.3) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs750367964, COSV100027665; called by muse, varscan2
- KRT86 | c.1126C>G p.Q376E | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99524913; called by muse, mutect2, varscan2
- LRRC8B | c.1393C>G p.L465V | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1425549802, COSV58374140, COSV58375629; called by muse, mutect2, varscan2
- MDM1 | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV57447150; called by muse, mutect2, varscan2
- MIPOL1 | c.678C>A p.N226K | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV59386252; called by muse, mutect2, varscan2
- MOV10 | c.1221G>T p.Q407H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV62491719; called by muse, mutect2, varscan2
- MST1R | c.3191C>G p.S1064C | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV56570031; called by muse, mutect2, varscan2
- NELL1 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV54278815; called by muse, mutect2, varscan2
- NLRP4 | c.1825G>T p.V609F | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV56716102, COSV56719004; called by muse, mutect2, varscan2
- NLRP4 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.927); catalogued as rs746532356, COSV56716114; called by muse, mutect2, varscan2
- NPC1L1 | c.1808T>C p.F603S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV56926403; called by muse, mutect2, varscan2
- NR3C1 | c.2315T>C p.L772P | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51543983; called by muse, mutect2, varscan2
- OMD | c.21A>G p.I7M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1294463903, COSV65020279; called by muse, mutect2, varscan2
- OR10S1 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV73342848; called by muse, mutect2, varscan2
- OR2L3 | c.42A>T p.L14F | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV100741947; called by muse, mutect2, varscan2
- OR5M11 | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV73141893; called by muse, mutect2, varscan2
- PALD1 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs141292267; called by muse, mutect2, varscan2
- PC | c.2525G>A p.R842Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774897991, CM158794, COSV58994885; called by muse, mutect2, varscan2
- PDPN | c.325T>C p.S109P (on ENST00000621990; = p.S185P on NM_006474.4) | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs1478016673, COSV53848744; called by muse, mutect2, varscan2
- PDXDC1 | c.1066A>T p.R356W | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV100363057; called by muse, mutect2
- PHOX2B | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432370889, COSV56929836; called by muse, varscan2
- PREX2 | c.1622A>G p.D541G | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV99906293; called by muse, mutect2, varscan2
- PRICKLE1 | c.2137A>G p.I713V | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58207858; called by muse, mutect2, varscan2
- RYR3 | c.7687C>T p.P2563S (on ENST00000389232; = p.P2564S on NM_001036.6) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV66795239; called by muse, mutect2, varscan2
- SIGLEC11 | c.270C>G p.N90K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.276); catalogued as COSV70222034; called by muse, mutect2, varscan2
- SLC35F4 | c.818T>A p.L273Q (on ENST00000339762 / NM_001352015.2; = p.L237Q on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60265344; called by muse, mutect2, varscan2
- THBS3 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs1371274246, COSV64249899; called by muse, mutect2, varscan2
- TRIM5 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.597); catalogued as COSV59900475; called by muse, mutect2, varscan2
- UBE4A | c.2077C>G p.Q693E (on ENST00000252108 / NM_001204077.2; = p.Q700E on NM_004788.4) | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV52803336; called by muse, mutect2, varscan2
- VIM | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56405296; called by muse, mutect2
- VWA2 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.198); catalogued as COSV53907646; called by muse, mutect2, varscan2
- ZFP69B | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV64315631; called by muse, mutect2, varscan2
- ZNF451 | c.1145A>C p.Q382P | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1284403066, COSV100674820; called by muse, varscan2
- ANXA8 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 37/403 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP2A2 | c.968C>G p.P323R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2
- BCOR | c.715_742del p.T239Rfs*18 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel
- CD27 | c.487_488del p.L163Gfs*2 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by pindel, varscan2
- ERCC2 | c.339A>T p.K113N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- FER1L6 | c.182_197del p.A61Dfs*5 | Frame Shift Del (DEL) | VAF 18/156 reads (12%) | called by mutect2, pindel
- IQSEC1 | c.440_441del p.Q147Lfs*35 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- LRRC4 | c.1736C>A p.T579K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.101); called by muse, mutect2
- OR52N5 | c.419_425del p.R140Lfs*18 | Frame Shift Del (DEL) | VAF 24/125 reads (19%) | called by mutect2, pindel, varscan2
- PARP14 | c.5389_*5del | Nonstop Mutation (DEL) | VAF 30/182 reads (16%) | called by mutect2, pindel
- RIPK4 | c.2288_2297del p.H763Rfs*103 (on ENST00000352483; = p.H715Rfs*103 on NM_020639.3) | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel
- SELENOP | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SPACA5B | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BACH2 | c.2268G>A p.A756= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs776040980, COSV57596829; called by mutect2, varscan2
- C19orf18 | c.156C>G p.T52= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as COSV100071709; called by muse, mutect2, varscan2
- CACNB4 | c.567T>A p.S189= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV52396195; called by muse, mutect2, varscan2
- CDC42BPA | c.3306G>A p.Q1102= (on ENST00000334218 / NM_001366019.2; = p.Q1089= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV62013363; called by muse, mutect2, varscan2
- CRB1 | c.2379C>A p.V793= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100957779; called by mutect2, varscan2
- DDX43 | c.1887G>A p.Q629= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs1332058586, COSV100943937; called by muse, mutect2, varscan2
- ELF2 | c.1725A>G p.S575= (on ENST00000379550 / NM_001331036.2; = p.S515= on NM_006874.4) | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV55493923; called by muse, mutect2, varscan2
- GPKOW | c.300G>A p.V100= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV50243206; called by muse, mutect2, varscan2
- HDAC11 | c.288C>T p.P96= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs1351129271, COSV55473636; called by muse, mutect2, varscan2
- HSPA5 | c.1923C>T p.P641= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV52336368; called by muse, mutect2, varscan2
- IQSEC2 | c.1449G>A p.P483= (on ENST00000642864 / NM_001111125.3; = p.P278= on NM_015075.2) | Silent (SNP) | VAF 66/132 reads (50%) | catalogued as rs200629644, COSV64726285; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- KRT13 | c.1032G>C p.G344= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV55840298; called by muse, mutect2, varscan2
- MYH13 | c.1248G>A p.G416= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV52832382; called by muse, mutect2, varscan2
- NPAS2 | c.660A>G p.L220= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV59558821; called by muse, mutect2, varscan2
- NRROS | c.1212G>C p.L404= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV60746456; called by muse, mutect2, varscan2
- NXN | c.1251C>T p.I417= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV61097560; called by muse, mutect2, varscan2
- OR2A5 | c.591G>A p.V197= | Silent (SNP) | VAF 59/353 reads (17%) | catalogued as COSV68738858; called by muse, mutect2, varscan2
- PARP12 | c.1557C>T p.R519= | Silent (SNP) | VAF 72/144 reads (50%) | catalogued as COSV54935154; called by muse, mutect2, varscan2
- RPH3A | c.288C>T p.N96= (on ENST00000389385 / NM_001143854.2; = p.N92= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV66991640; called by muse, mutect2, varscan2
- TMED5 | c.96C>G p.L32= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100159513, COSV58143595, COSV58144483; called by muse, mutect2, varscan2
- TPH2 | c.135C>T p.D45= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs74510566, COSV61590555; called by muse, varscan2
- ZNF280B | c.12A>G p.S4= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV64529086; called by muse, mutect2, varscan2
- ATP5MD | c.-9-1902_-9-1884del | Intron (DEL) | VAF 14/118 reads (12%) | called by mutect2, pindel
- SNORD114-11 | n.42G>A | RNA (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10361-5467C>T | Intron (SNP) | VAF 69/106 reads (65%) | catalogued as COSV60136375; called by muse, mutect2, varscan2
